Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A29Q, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A29Q-06A (Metastatic).

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

CLINICAL DETAILS

Melanoma metastasis right arm. (FNB +ve). Ref: . Histopathology.

FROZEN SECTION REPORT

Fresh tissue was taken for tumour banking (Registrar/ Pathologist: . Time:).

MACROSCOPIC DESCRIPTION

(Dr

"R ARM METASTASIS". An unorientated ellipse of skin 52 x 22 x 22mm in depth. There is a subcutaneous lump up to 10mm across, pale tan in colour firm in consistency, lies 2mm away from the blue inked margin. The deep margin inked blue. Two slices of the entire subcutaneous mass embedded in blocks A and B.

MICROSCOPIC REPORT

The sections show a nodule of METASTATIC MALIGNANT MELANOMA within the subcutis. There is no epidermal invasion. Very occasional cells have cytoplasmic pigment. The tumour consists of solid sheets and nests of cells with some areas of necrosis. The nodule is composed of pleomorphic cells with eccentric cytoplasm and hyperchromatic nuclei. The nodule measures 11mm in diameter. No convincing vascular invasion is seen.

The tumour is approximately 5mm from the closest deep fatty resection margin.

SUMMARY

SKIN EXCISION RIGHT ARM - metastatic malignant melanoma.

REPORTED BY: Dr.

ICD-0-3

Melanoma, NOS 8720/3

Site: Subcutaneous tissue,

ARM

C49.1

W 6/2/11

Source: NCI Genomic Data Commons file 06a679d1-733b-4954-9724-8fd1ffd2ebe0 (TCGA-EE-A29Q.4ED10518-B475-433F-945A-1A97C8B6041C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).